EXCEPTIONAL_RESPONDERS case ER-ADBL — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a4e7b021-3c28-4c5a-ba2a-30bd314752c9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1945; Vital status: Alive.

Diagnoses (1)
1. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin of lower limb and hip; Site of resection or biopsy: Skin of lower limb and hip; Classification of tumor: metastasis; Age at diagnosis: 65.7 years (23,981 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Days to last follow up: 1,619 days (4.4 years); Days to best overall response: 1,045 days (2.9 years); Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Ipilimumab; Days to treatment start: 929 days (2.5 years); Days to treatment end: 992 days (2.7 years).

Follow-up (1 entry)
- Days to follow up: 1,619 days (4.4 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 1,619 days (4.4 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ADBL-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-ADBL-NT1-A-2-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-ADBL-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
